Somatic mutation profile of cancer-model specimen HCM-CSHL-0369-D37-85P (3D Organoid; aliquot HCM-CSHL-0369-D37-85P-01D-A78T-36), derived from the premalignant tumor of HCMI case HCM-CSHL-0369-D37, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Tubulovillous adenoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage 0; Tumor grade: GX; Age at diagnosis: 62.2 years (22,734 days).
Specimen HCM-CSHL-0369-D37-85P: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Premalignant; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a20a396f-5e41-4c5f-a767-92c278e5a328.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0369-D37-10A (Blood Derived Normal), aliquot HCM-CSHL-0369-D37-10A-01D-A78T-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2151c0de-9982-4e3e-8bc3-1ff95e510955

The open-access MAF lists 469 somatic variants for this specimen: 322 protein-altering or splice-affecting, 91 silent, 56 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 291, Silent 91, Intron 35, Nonsense Mutation 16, Splice Site 10, 3'UTR 8, 5'UTR 6, RNA 3, Frame Shift Del 3, 5'Flank 3, Frame Shift Ins 2, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.4463del p.L1488Yfs*19 | Frame Shift Del (DEL) | VAF 68/165 reads (41%) | catalogued as rs1114167577, COSV57389473; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- F11 | c.802C>T p.R268C | Missense Mutation (SNP) | VAF 140/308 reads (45%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.967); catalogued as rs763496524, CM035499, COSV53004761; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.1393C>T p.R465C (on ENST00000281708 / NM_001349798.2; = p.R385C on NM_018315.5) | Missense Mutation (SNP) | VAF 30/138 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867384286, COSV55891008, COSV55897912, COSV99654845; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.437C>T p.A146V | Missense Mutation (SNP) | VAF 146/202 reads (72%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.884); catalogued as rs1057519725, COSV55498939; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- ABCA8 | c.1966G>A p.A656T | Missense Mutation (SNP) | VAF 39/119 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.22); catalogued as rs755088665, COSV52210429, COSV52211116; called by muse, mutect2, varscan2
- ACAP1 | c.1586G>A p.R529Q | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.537); catalogued as rs767071679, COSV50138819; called by muse, mutect2, varscan2
- ACVR2A | c.286dup p.D96Gfs*4 | Frame Shift Ins (INS) | VAF 13/111 reads (12%) | catalogued as COSV54018845; called by mutect2, varscan2
- ADAMTS2 | c.3557C>A p.P1186H | Missense Mutation (SNP) | VAF 26/463 reads (6%) | SIFT tolerated, low confidence (0.55); PolyPhen possibly damaging (0.533); catalogued as COSV52382438; called by muse, mutect2
- ALK | c.3602G>T p.G1201V | Missense Mutation (SNP) | VAF 22/546 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1187025942, COSV66557297; called by muse, mutect2
- ALS2 | c.3292G>T p.D1098Y | Missense Mutation (SNP) | VAF 14/386 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV51891152; called by muse, mutect2
- AMIGO1 | c.515G>A p.R172H | Missense Mutation (SNP) | VAF 135/370 reads (36%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as rs1455628186; called by muse, mutect2, varscan2
- ANXA10 | c.85G>T p.A29S | Missense Mutation (SNP) | VAF 15/222 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV63739248; called by muse, mutect2
- ASNSD1 | c.1268G>A p.R423Q | Missense Mutation (SNP) | VAF 25/168 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775560677, COSV53622874; called by muse, mutect2, varscan2
- ATM | c.3719A>G p.N1240S | Missense Mutation (SNP) | VAF 34/74 reads (46%) | SIFT tolerated (0.13); PolyPhen benign (0.143); catalogued as rs1555092536; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP5F1D | c.479A>G p.N160S | Missense Mutation (SNP) | VAF 285/372 reads (77%) | SIFT tolerated (0.49); PolyPhen benign (0.005); catalogued as rs372801460; called by muse, mutect2, varscan2
- AXDND1 | c.953G>A p.R318H | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT tolerated (0.63); PolyPhen benign (0.286); catalogued as rs200125774, COSV62639986; called by muse, mutect2, varscan2
- BACE1 | c.404G>A p.G135D | Missense Mutation (SNP) | VAF 11/232 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs977445206; called by muse, mutect2
- BCHE | c.770C>T p.A257V | Missense Mutation (SNP) | VAF 11/268 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.133); catalogued as rs1385455803, COSV104387694; called by muse, mutect2
- BRCA2 | c.8257C>T p.L2753F | Missense Mutation (SNP) | VAF 69/149 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.265); catalogued as COSV66452544; called by muse, mutect2, varscan2
- CACNA1F | c.142C>A p.P48T | Missense Mutation (SNP) | VAF 28/544 reads (5%) | SIFT tolerated (0.61); PolyPhen benign (0.115); catalogued as rs782524571; called by muse, mutect2
- CACNA1H | c.4560C>A p.D1520E | Missense Mutation (SNP) | VAF 202/418 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as rs1301892178, COSV100673663; called by muse, mutect2, varscan2
- CBX2 | c.977G>A p.G326D | Missense Mutation (SNP) | VAF 8/189 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.844); catalogued as rs782696333; called by muse, mutect2
- CCDC116 | c.176G>A p.G59D | Missense Mutation (SNP) | VAF 15/434 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.123); catalogued as COSV99489039; called by muse, mutect2
- CDCP2 | c.1151G>A p.G384D | Missense Mutation (SNP) | VAF 18/545 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.027); catalogued as rs909182596, COSV61283695; called by muse, mutect2
- CERKL | c.896C>A p.A299E (on ENST00000339098 / NM_001030311.2; = p.A273E on NM_201548.5) | Missense Mutation (SNP) | VAF 126/366 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs1056709588; called by muse, mutect2, varscan2
- CILP | c.2526C>A p.F842L | Missense Mutation (SNP) | VAF 26/449 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV56023076; called by muse, mutect2
- CNTN1 | c.826C>T p.R276W | Missense Mutation (SNP) | VAF 46/300 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs144047921; called by muse, varscan2
- COL11A1 | c.1886A>G p.D629G | Missense Mutation (SNP) | VAF 12/346 reads (3%) | SIFT deleterious (0.04); PolyPhen benign (0.21); catalogued as rs1371731461; called by muse, mutect2
- COL16A1 | c.586C>T p.P196S | Missense Mutation (SNP) | VAF 27/548 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.5); catalogued as COSV99593736; called by muse, mutect2
- COL22A1 | c.2966C>T p.P989L | Missense Mutation (SNP) | VAF 132/265 reads (50%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.842); catalogued as rs370576971; called by muse, mutect2, varscan2
- COLEC11 | c.477G>T p.E159D | Missense Mutation (SNP) | VAF 29/633 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV52591852; called by muse, mutect2
- CREB3L3 | c.1241C>T p.S414L | Missense Mutation (SNP) | VAF 160/692 reads (23%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as rs745524129, COSV50193122; called by muse, mutect2, varscan2
- CSF2RB | c.1705C>A p.P569T | Missense Mutation (SNP) | VAF 17/349 reads (5%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.476); catalogued as COSV99453161; called by muse, mutect2
- CUL4A | c.1880C>T p.T627M (on ENST00000375440 / NM_001008895.4; = p.T527M on NM_003589.3) | Missense Mutation (SNP) | VAF 53/99 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs760636923, COSV58371794; called by muse, mutect2, varscan2
- DCAF12L2 | c.1190C>A p.P397H | Missense Mutation (SNP) | VAF 57/276 reads (21%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.541); catalogued as COSV63580380; called by muse, mutect2, varscan2
- DCC | c.3287G>T p.S1096I | Missense Mutation (SNP) | VAF 24/538 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as COSV101473549; called by muse, mutect2
- DHRS11 | c.476C>G p.P159R | Missense Mutation (SNP) | VAF 11/122 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.024); catalogued as rs150477741; called by muse, mutect2
- DMGDH | c.1408C>T p.R470* | Nonsense Mutation (SNP) | VAF 304/660 reads (46%) | catalogued as rs745676529, COSV54861370; called by muse, mutect2, varscan2
- DOT1L | c.2770G>A p.G924S | Missense Mutation (SNP) | VAF 91/384 reads (24%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.003); catalogued as rs1212427702; called by muse, mutect2, varscan2
- DRC7 | c.1657C>G p.Q553E | Missense Mutation (SNP) | VAF 12/395 reads (3%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV61052904; called by muse, mutect2
- ELANE | c.406G>T p.A136S | Missense Mutation (SNP) | VAF 25/749 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV55049813; called by muse, mutect2
- ELMOD1 | c.563C>T p.A188V | Missense Mutation (SNP) | VAF 59/138 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.204); catalogued as rs763943002; called by muse, mutect2, varscan2
- ENO2 | c.1192C>A p.P398T | Missense Mutation (SNP) | VAF 14/501 reads (3%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.945); catalogued as COSV99980369; called by muse, mutect2
- ERCC3 | c.2255G>C p.G752A | Missense Mutation (SNP) | VAF 24/522 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53427317; called by muse, mutect2
- FAM90A1 | c.631C>T p.P211S | Missense Mutation (SNP) | VAF 257/1300 reads (20%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.723); catalogued as rs374455262; called by muse, mutect2, varscan2
- FCGBP | c.2696C>T p.A899V | Missense Mutation (SNP) | VAF 39/607 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.216); catalogued as rs542721751; called by muse, mutect2
- FLT4 | c.853C>A p.Q285K | Missense Mutation (SNP) | VAF 27/654 reads (4%) | SIFT tolerated (0.95); PolyPhen benign (0.038); catalogued as rs1279584243; called by muse, mutect2
- FOXA2 | c.701C>T p.T234I (on ENST00000377115 / NM_153675.3; = p.T240I on NM_021784.5) | Missense Mutation (SNP) | VAF 102/479 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs766470566; called by muse, mutect2, varscan2
- FUT2 | c.217G>T p.G73W | Missense Mutation (SNP) | VAF 20/610 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101218034; called by muse, mutect2
- GABRA5 | c.1278C>A p.D426E | Missense Mutation (SNP) | VAF 18/415 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59485306; called by muse, mutect2
- GATA2 | c.1280C>A p.P427H | Missense Mutation (SNP) | VAF 16/344 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.013); catalogued as COSV100351489; called by muse, mutect2
- GLIS2 | c.380C>G p.P127R | Missense Mutation (SNP) | VAF 29/354 reads (8%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.731); catalogued as COSV52109838; called by muse, mutect2
- GPRASP2 | c.431G>T p.G144V | Missense Mutation (SNP) | VAF 17/252 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.224); catalogued as COSV59991293; called by muse, mutect2
- GPRASP2 | c.1514G>T p.G505V | Missense Mutation (SNP) | VAF 15/251 reads (6%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV59992845; called by muse, mutect2
- HECW1 | c.4648G>T p.G1550W | Missense Mutation (SNP) | VAF 84/896 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101224382; called by muse, mutect2
- HMCN1 | c.1562C>T p.P521L | Missense Mutation (SNP) | VAF 125/275 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750199952, COSV99623606; called by muse, mutect2, varscan2
- HMCN2 | c.2085C>A p.D695E | Missense Mutation (SNP) | VAF 15/326 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.026); catalogued as rs1311299862; called by muse, mutect2
- HTR5A | c.946C>A p.P316T | Missense Mutation (SNP) | VAF 35/790 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55280885; called by muse, mutect2
- IBSP | c.706G>C p.E236Q | Missense Mutation (SNP) | VAF 14/288 reads (5%) | SIFT tolerated (0.35); PolyPhen benign (0.012); catalogued as COSV56896764; called by muse, mutect2
- IQCK | c.694C>T p.R232C | Missense Mutation (SNP) | VAF 95/212 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750703451, COSV57521319; called by muse, mutect2
- ITK | c.158G>T p.G53V | Missense Mutation (SNP) | VAF 194/383 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101439852, COSV70065503; called by muse, mutect2, varscan2
- JARID2 | c.2263G>A p.E755K | Missense Mutation (SNP) | VAF 11/198 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.96); catalogued as rs1417007497, COSV59191398; called by muse, mutect2
- KCNK18 | c.813A>T p.E271D | Missense Mutation (SNP) | VAF 18/377 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as COSV57972012; called by muse, mutect2
- KRTAP19-3 | c.25G>T p.G9* | Nonsense Mutation (SNP) | VAF 14/307 reads (5%) | catalogued as COSV61854918; called by muse, mutect2
- LAS1L | c.1372G>A p.A458T | Missense Mutation (SNP) | VAF 115/271 reads (42%) | SIFT tolerated (0.29); PolyPhen benign (0.015); catalogued as rs750728472; called by muse, mutect2, varscan2
- LENG1 | c.56G>A p.R19H | Missense Mutation (SNP) | VAF 45/339 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.636); catalogued as rs746834192, COSV55362945; called by muse, mutect2, varscan2
- LIPG | c.176C>A p.P59Q | Missense Mutation (SNP) | VAF 23/485 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.027); catalogued as rs1369488728; called by muse, mutect2
- LRRC10B | c.92G>T p.R31L | Missense Mutation (SNP) | VAF 200/403 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.034); catalogued as rs1238259152; called by muse, mutect2, varscan2
- MAMDC4 | c.529G>C p.G177R | Missense Mutation (SNP) | VAF 12/284 reads (4%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as rs1313687818; called by muse, mutect2
- MAMLD1 | c.1949C>A p.A650E | Missense Mutation (SNP) | VAF 28/602 reads (5%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.117); catalogued as COSV99476724; called by muse, mutect2
- MAST3 | c.2146G>A p.V716I | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as rs766988885; called by muse, varscan2
- MC3R | c.70C>G p.P24A | Missense Mutation (SNP) | VAF 15/334 reads (4%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV99710814; called by muse, mutect2
- MRAS | c.314G>T p.R105L | Missense Mutation (SNP) | VAF 21/304 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV56671535; called by muse, mutect2
- MTG2 | c.1027G>A p.V343I | Missense Mutation (SNP) | VAF 120/255 reads (47%) | SIFT tolerated (0.6); PolyPhen benign (0.03); catalogued as rs146666461; called by muse, mutect2, varscan2
- MTUS2 | c.2321C>A p.A774E | Missense Mutation (SNP) | VAF 27/584 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101462068; called by muse, mutect2
- MYH8 | c.4972C>A p.L1658I | Missense Mutation (SNP) | VAF 26/508 reads (5%) | SIFT tolerated (0.5); PolyPhen benign (0.007); catalogued as COSV101238190; called by muse, mutect2
- MYO7B | c.3491C>T p.P1164L | Missense Mutation (SNP) | VAF 21/450 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as rs1441139049; called by muse, mutect2
- MYO9B | c.6182G>A p.R2061Q | Missense Mutation (SNP) | VAF 120/156 reads (77%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs756634070; called by muse, varscan2
- NEB | c.11972T>C p.I3991T | Missense Mutation (SNP) | VAF 66/293 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as rs774949638; called by muse, mutect2, varscan2
- NMUR2 | c.495G>T p.R165S | Missense Mutation (SNP) | VAF 14/237 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.272); catalogued as COSV54919440, COSV54919973; called by muse, mutect2
- NPAP1 | c.2716G>T p.G906W | Missense Mutation (SNP) | VAF 16/320 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as COSV61505137; called by muse, mutect2
- NRP1 | c.509G>A p.S170N | Missense Mutation (SNP) | VAF 12/289 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55160331; called by muse, mutect2
- OLFML2A | c.1711C>T p.R571W | Missense Mutation (SNP) | VAF 194/432 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs369965570, COSV56585775, COSV99992653; called by muse, varscan2
- PALD1 | c.2422G>T p.A808S | Missense Mutation (SNP) | VAF 63/402 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.297); catalogued as COSV54971004; called by muse, mutect2, varscan2
- PCDHA10 | c.190C>T p.R64W | Missense Mutation (SNP) | VAF 365/370 reads (99%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.993); catalogued as rs1250461159, COSV56479266; called by muse, mutect2, varscan2
- PCDHA13 | c.1786G>A p.A596T | Missense Mutation (SNP) | VAF 299/656 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs1313975286, COSV56487940; called by muse, mutect2, varscan2
- PCDHB12 | c.1903G>A p.A635T | Missense Mutation (SNP) | VAF 28/1062 reads (3%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.432); catalogued as rs373006083; called by muse, mutect2
- PDHA2 | c.553G>A p.D185N | Missense Mutation (SNP) | VAF 23/264 reads (9%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as rs267600306, COSV54776945; called by muse, mutect2
- PDZD2 | c.6844C>T p.P2282S | Missense Mutation (SNP) | VAF 18/313 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.419); catalogued as COSV56863413; called by muse, mutect2
- PHEX | c.2148-1G>A p.X716_splice | Splice Site (SNP) | VAF 15/392 reads (4%) | catalogued as CS092784; called by muse, mutect2
- PIEZO2 | c.2960C>T p.T987I | Missense Mutation (SNP) | VAF 128/335 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs1323885459; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLA2G4C | c.1592C>T p.P531L | Missense Mutation (SNP) | VAF 36/195 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as rs751202291; called by muse, mutect2, varscan2
- PLEKHH2 | c.3257G>A p.R1086H | Missense Mutation (SNP) | VAF 25/41 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775706144; called by muse, mutect2, varscan2
- PPP1R3A | c.1456C>T p.R486* | Nonsense Mutation (SNP) | VAF 27/268 reads (10%) | catalogued as rs780306610, COSV52882236; called by muse, mutect2, varscan2
- PPP5C | c.1183C>T p.R395C | Missense Mutation (SNP) | VAF 56/172 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.561); catalogued as COSV50141930; called by muse, mutect2, varscan2
- PRDM9 | c.8C>A p.P3H | Missense Mutation (SNP) | VAF 16/582 reads (3%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.536); catalogued as COSV99690053, COSV99690693; called by muse, mutect2
- PTPRS | c.4942G>T p.A1648S | Missense Mutation (SNP) | VAF 22/623 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV53610920; called by muse, mutect2
- QKI | c.229G>T p.G77* | Nonsense Mutation (SNP) | VAF 8/184 reads (4%) | catalogued as COSV51698720, COSV99275803; called by muse, mutect2
- RBKS | c.412G>T p.A138S | Missense Mutation (SNP) | VAF 10/194 reads (5%) | SIFT tolerated (0.69); PolyPhen benign (0.001); catalogued as rs1399626026; called by muse, mutect2
- RBMXL3 | c.950G>T p.W317L | Missense Mutation (SNP) | VAF 10/151 reads (7%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as rs782348696; called by muse, mutect2
- RBP3 | c.2185C>A p.L729I | Missense Mutation (SNP) | VAF 29/636 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs1372129460; called by muse, mutect2
- RGSL1 | c.1147C>A p.P383T | Missense Mutation (SNP) | VAF 11/245 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs796651047; called by muse, mutect2
- RPL11 | c.452G>T p.G151V (on ENST00000374550 / NM_001199802.1; = p.G152V on NM_000975.5) | Missense Mutation (SNP) | VAF 27/693 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.659); catalogued as COSV65779073; called by muse, mutect2
- RPL36A | c.108G>C p.Q36H | Missense Mutation (SNP) | VAF 82/164 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.122); catalogued as COSV100864959; called by muse, mutect2, varscan2
- SALL3 | c.3594G>C p.K1198N | Missense Mutation (SNP) | VAF 23/466 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV73306167; called by muse, mutect2
- SEMA5B | c.2377C>T p.R793W | Missense Mutation (SNP) | VAF 24/348 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.943); catalogued as COSV99532698; called by muse, mutect2
- SLC1A6 | c.1057C>A p.H353N | Missense Mutation (SNP) | VAF 13/341 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as COSV55672326, COSV55675353; called by muse, mutect2
- SLC1A6 | c.832T>A p.F278I | Missense Mutation (SNP) | VAF 24/616 reads (4%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.733); catalogued as COSV55673559; called by muse, mutect2
- SLC33A1 | c.1211G>C p.G404A | Missense Mutation (SNP) | VAF 10/194 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.062); catalogued as COSV100848366; called by muse, mutect2
- SLC39A7 | c.1288G>A p.V430I | Missense Mutation (SNP) | VAF 154/721 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.187); catalogued as rs751803145, COSV63002958; called by muse, mutect2, varscan2
- SLC6A12 | c.830G>A p.R277H | Missense Mutation (SNP) | VAF 52/255 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs759619929, COSV100675120; called by muse, mutect2, varscan2
- SLFN11 | c.422G>A p.R141H | Missense Mutation (SNP) | VAF 109/207 reads (53%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as rs777285142, COSV57697771, COSV57697775; called by muse, mutect2, varscan2
- SORCS3 | c.146C>A p.P49Q | Missense Mutation (SNP) | VAF 24/426 reads (6%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as rs974141784; called by muse, mutect2
- SOX3 | c.62C>G p.A21G | Missense Mutation (SNP) | VAF 110/757 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.017); catalogued as COSV65167953; called by muse, mutect2, varscan2
- SPINT1 | c.1310G>T p.C437F (on ENST00000344051 / NM_181642.3; = p.C421F on NM_003710.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1206560907, COSV100689071; called by muse, mutect2, varscan2
- ST6GAL2 | c.349G>T p.G117W | Missense Mutation (SNP) | VAF 11/274 reads (4%) | PolyPhen possibly damaging (0.793); catalogued as COSV64526190, COSV64532121, COSV64532267; called by muse, mutect2
- TCF4 | c.1166G>A p.R389H | Missense Mutation (SNP) | VAF 86/460 reads (19%) | SIFT tolerated (0.36); PolyPhen benign (0.051); catalogued as rs1188916145; called by muse, mutect2, varscan2
- TMC1 | c.2177C>T p.A726V | Missense Mutation (SNP) | VAF 157/370 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.033); catalogued as rs573874378, COSV52769526; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TRANK1 | c.1238C>T p.P413L | Missense Mutation (SNP) | VAF 164/436 reads (38%) | SIFT tolerated (0.28); PolyPhen benign (0.028); catalogued as rs749529987; called by muse, mutect2, varscan2
- TXNDC5 | c.458G>T p.G153V | Missense Mutation (SNP) | VAF 12/249 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs888122891; called by muse, mutect2
- USP48 | c.2186G>C p.R729T | Missense Mutation (SNP) | VAF 106/219 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.32); catalogued as COSV57613775; called by muse, mutect2, varscan2
- ZZEF1 | c.300C>A p.F100L | Missense Mutation (SNP) | VAF 34/782 reads (4%) | SIFT tolerated (0.05); PolyPhen benign (0.141); catalogued as COSV56800771; called by muse, mutect2
- ABCA3 | c.1360G>C p.G454R | Missense Mutation (SNP) | VAF 36/921 reads (4%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.883); called by muse, mutect2
- ABCA6 | c.1877G>T p.G626V | Missense Mutation (SNP) | VAF 13/320 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- ABCF3 | c.1445A>G p.D482G | Missense Mutation (SNP) | VAF 141/287 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.392); called by muse, mutect2, varscan2
- ABR | c.1072C>A p.P358T (on ENST00000302538 / NM_021962.5; = p.P321T on NM_001092.5) | Missense Mutation (SNP) | VAF 16/186 reads (9%) | SIFT tolerated (0.26); PolyPhen benign (0.044); called by muse, mutect2
- AC011005.1 | c.358G>A p.V120I | Missense Mutation (SNP) | VAF 27/806 reads (3%) | SIFT tolerated (0.68); PolyPhen possibly damaging (0.54); called by muse, mutect2
- AC068580.4 | c.80del p.H27Pfs*20 | Frame Shift Del (DEL) | VAF 96/637 reads (15%) | called by mutect2, pindel, varscan2
- ACVR1B | c.647G>T p.G216V | Missense Mutation (SNP) | VAF 10/182 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ADGRB2 | c.3002C>T p.A1001V | Missense Mutation (SNP) | VAF 102/201 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ADRB3 | c.89T>G p.L30R | Missense Mutation (SNP) | VAF 21/566 reads (4%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.878); called by muse, mutect2
- AGK | c.254C>T p.A85V | Missense Mutation (SNP) | VAF 12/240 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); called by muse, mutect2
- AL645922.1 | c.649G>T p.A217S | Missense Mutation (SNP) | VAF 67/436 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.348); called by muse, mutect2, varscan2
- AMBN | c.379C>T p.L127F | Missense Mutation (SNP) | VAF 194/470 reads (41%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- AMBRA1 | c.2653C>T p.Q885* (on ENST00000458649 / NM_001367468.1; = p.Q795* on NM_017749.3 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 112/224 reads (50%) | called by muse, mutect2, varscan2
- AP3B2 | c.1854C>A p.D618E | Missense Mutation (SNP) | VAF 8/121 reads (7%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.662); called by muse, mutect2
- APEH | c.607-1G>T p.X203_splice | Splice Site (SNP) | VAF 13/272 reads (5%) | called by muse, mutect2
- APOA1 | c.96G>T p.W32C | Missense Mutation (SNP) | VAF 10/205 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); called by muse, mutect2
- ASIC4 | c.884A>G p.N295S | Missense Mutation (SNP) | VAF 14/260 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.039); called by muse, mutect2
- BEND3 | c.1090G>T p.D364Y | Missense Mutation (SNP) | VAF 16/366 reads (4%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.092); called by muse, mutect2
- BPI | c.608G>A p.S203N (on ENST00000262865; = p.S199N on NM_001725.3) | Missense Mutation (SNP) | VAF 14/224 reads (6%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2
- C12orf42 | c.857C>A p.P286H | Missense Mutation (SNP) | VAF 16/486 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); called by muse, mutect2
- C16orf86 | c.791C>T p.A264V | Missense Mutation (SNP) | VAF 16/399 reads (4%) | SIFT tolerated (0.46); PolyPhen benign (0.006); called by muse, mutect2
- C1S | c.1463G>C p.G488A | Missense Mutation (SNP) | VAF 29/776 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.27); called by muse, mutect2
- CACNA1E | c.997C>A p.P333T | Missense Mutation (SNP) | VAF 42/266 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CBFA2T3 | c.1924C>A p.P642T | Missense Mutation (SNP) | VAF 8/128 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.253); called by muse, mutect2
- CCDC87 | c.1478A>T p.E493V | Missense Mutation (SNP) | VAF 11/238 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); called by muse, mutect2
- CEP170 | c.550G>T p.G184W | Missense Mutation (SNP) | VAF 14/274 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CERS4 | c.187C>A p.P63T | Missense Mutation (SNP) | VAF 15/384 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- CES3 | c.722C>T p.S241F | Missense Mutation (SNP) | VAF 10/170 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- CFAP46 | c.7075del p.S2359Lfs*18 | Frame Shift Del (DEL) | VAF 76/193 reads (39%) | called by mutect2, pindel, varscan2
- CHAMP1 | c.1501C>T p.P501S | Missense Mutation (SNP) | VAF 13/267 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.007); called by muse, mutect2
- CHST2 | c.313C>T p.R105C | Missense Mutation (SNP) | VAF 32/185 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.586); called by muse, mutect2, varscan2
- CLSTN2 | c.1650G>C p.L550F | Missense Mutation (SNP) | VAF 12/172 reads (7%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.997); called by muse, mutect2
- COL18A1 | c.3975_3983del p.X1325_splice (on ENST00000359759 / NM_130444.3; = p.X1090_splice on NM_030582.4) | Splice Site (DEL) | VAF 51/116 reads (44%) | called by mutect2, pindel, varscan2
- COL3A1 | c.4129G>T p.A1377S | Missense Mutation (SNP) | VAF 139/253 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.61); called by muse, mutect2, varscan2
- COL4A6 | c.2563G>T p.G855* | Nonsense Mutation (SNP) | VAF 12/291 reads (4%) | called by muse, mutect2
- CTAG2 | c.191C>T p.P64L | Missense Mutation (SNP) | VAF 327/594 reads (55%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- DCLK1 | c.926C>A p.A309D | Missense Mutation (SNP) | VAF 10/208 reads (5%) | SIFT tolerated (0.27); PolyPhen benign (0.197); called by muse, mutect2
- DIP2B | c.2827C>A p.P943T | Missense Mutation (SNP) | VAF 19/379 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- DUS2 | c.1130G>T p.W377L | Missense Mutation (SNP) | VAF 84/225 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.479); called by muse, mutect2, varscan2
- EEFSEC | c.710A>T p.Q237L | Missense Mutation (SNP) | VAF 12/226 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2
- EIF2S2 | c.337C>G p.P113A | Missense Mutation (SNP) | VAF 93/223 reads (42%) | SIFT tolerated (0.76); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- EIF3I | c.168G>T p.W56C | Missense Mutation (SNP) | VAF 19/430 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2
- EMC6 | c.305T>G p.F102C | Missense Mutation (SNP) | VAF 40/168 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- EMILIN1 | c.1259C>A p.P420H | Missense Mutation (SNP) | VAF 15/375 reads (4%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.754); called by muse, mutect2
- ENG | c.1813C>G p.L605V | Missense Mutation (SNP) | VAF 27/648 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- ENOX2 | c.296A>G p.E99G (on ENST00000338144 / NM_001382520.1; = p.E70G on NM_006375.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2
- FAM181A | c.652G>T p.G218* | Nonsense Mutation (SNP) | VAF 22/434 reads (5%) | called by muse, mutect2
- FAT1 | c.6668C>A p.P2223H | Missense Mutation (SNP) | VAF 73/142 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FAT3 | c.580T>A p.Y194N | Missense Mutation (SNP) | VAF 9/151 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- FIBP | c.851G>T p.R284L (on ENST00000338369 / NM_198897.2; = p.R277L on NM_004214.5) | Missense Mutation (SNP) | VAF 74/370 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.78); called by muse, mutect2, varscan2
- FIGNL2 | c.482G>T p.G161V | Missense Mutation (SNP) | VAF 20/334 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.154); called by muse, mutect2
- FIZ1 | c.529G>T p.A177S | Missense Mutation (SNP) | VAF 12/263 reads (5%) | SIFT tolerated (0.44); PolyPhen benign (0.081); called by muse, mutect2
- FKBP7 | c.163C>G p.L55V | Missense Mutation (SNP) | VAF 18/440 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.202); called by muse, mutect2
- FLG | c.6427G>A p.G2143R | Missense Mutation (SNP) | VAF 28/700 reads (4%) | SIFT tolerated (0.5); PolyPhen benign (0.031); called by muse, mutect2
- FLG | c.790G>T p.D264Y | Missense Mutation (SNP) | VAF 26/962 reads (3%) | SIFT tolerated (0.8); PolyPhen benign (0.049); called by muse, mutect2
- FPGS | c.526C>A p.P176T | Missense Mutation (SNP) | VAF 18/530 reads (3%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by muse, mutect2
- GC | c.*26-1G>T | Splice Site (SNP) | VAF 12/204 reads (6%) | called by muse, mutect2
- GCNA | c.374A>G p.D125G | Missense Mutation (SNP) | VAF 157/394 reads (40%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GDF7 | c.1231C>T p.P411S | Missense Mutation (SNP) | VAF 37/610 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- GJA8 | c.560C>A p.P187H | Missense Mutation (SNP) | VAF 19/551 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GNRHR | c.27G>T p.Q9H | Missense Mutation (SNP) | VAF 161/318 reads (51%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- GPR19 | c.1064G>A p.S355N | Missense Mutation (SNP) | VAF 13/274 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2
- GPR62 | c.707G>A p.G236E | Missense Mutation (SNP) | VAF 30/680 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.369); called by muse, mutect2
- GRAP2 | c.940C>A p.H314N | Missense Mutation (SNP) | VAF 14/398 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.001); called by muse, mutect2
- GUCA1A | c.370C>T p.P124S | Missense Mutation (SNP) | VAF 24/676 reads (4%) | SIFT tolerated (0.7); PolyPhen benign (0.173); called by muse, mutect2
- HECTD4 | c.7189C>T p.R2397W | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HNRNPU | c.356G>T p.G119V | Missense Mutation (SNP) | VAF 102/663 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- IFNL3 | c.263G>T p.R88M | Missense Mutation (SNP) | VAF 14/360 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.404); called by muse, mutect2
- IGSF1 | c.2804A>G p.E935G | Missense Mutation (SNP) | VAF 14/418 reads (3%) | SIFT tolerated (0.21); PolyPhen benign (0.308); called by muse, mutect2
- INSL3 | c.373C>A p.L125M | Missense Mutation (SNP) | VAF 22/712 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- IQCN | c.2855G>C p.G952A | Missense Mutation (SNP) | VAF 22/546 reads (4%) | SIFT tolerated (0.72); PolyPhen benign (0.067); called by muse, mutect2
- IQGAP2 | c.1486G>T p.D496Y | Missense Mutation (SNP) | VAF 96/177 reads (54%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.511); called by muse, mutect2, varscan2
- JADE2 | c.1697C>G p.S566* | Nonsense Mutation (SNP) | VAF 123/284 reads (43%) | called by muse, varscan2
- JMY | c.2779G>T p.A927S | Missense Mutation (SNP) | VAF 15/308 reads (5%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.991); called by muse, mutect2
- KDM5C | c.2832G>C p.R944S | Missense Mutation (SNP) | VAF 19/574 reads (3%) | SIFT tolerated (0.39); PolyPhen benign (0.14); called by muse, mutect2
- KIAA0232 | c.3329C>A p.P1110Q | Missense Mutation (SNP) | VAF 14/427 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KIAA0319 | c.1262A>G p.N421S | Missense Mutation (SNP) | VAF 42/95 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.648); called by muse, mutect2, varscan2
- KIF16B | c.2257G>A p.E753K | Missense Mutation (SNP) | VAF 23/464 reads (5%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.989); called by muse, mutect2
- KLHDC7B | c.220C>G p.P74A (on ENST00000395676; = p.P715A on NM_138433.5) | Missense Mutation (SNP) | VAF 16/442 reads (4%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.001); called by muse, mutect2
- KLHL20 | c.950G>T p.G317V | Missense Mutation (SNP) | VAF 8/118 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.046); called by muse, mutect2
- KLHL33 | c.494G>T p.G165V | Missense Mutation (SNP) | VAF 18/393 reads (5%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.761); called by muse, mutect2
- KMT5A | c.382C>A p.P128T | Missense Mutation (SNP) | VAF 24/666 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.053); called by muse, mutect2
- KMT5C | c.1091C>T p.P364L | Missense Mutation (SNP) | VAF 17/548 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.074); called by muse, mutect2
- KNDC1 | c.1157G>C p.G386A | Missense Mutation (SNP) | VAF 15/329 reads (5%) | SIFT tolerated (0.8); PolyPhen benign (0.009); called by muse, mutect2
- KRTAP10-11 | c.111C>A p.C37* | Nonsense Mutation (SNP) | VAF 22/455 reads (5%) | called by muse, mutect2
- LDB3 | c.823T>A p.F275I | Missense Mutation (SNP) | VAF 14/364 reads (4%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.994); called by muse, mutect2
- LMNB2 | c.1382G>T p.G461V | Missense Mutation (SNP) | VAF 39/954 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.139); called by muse, mutect2
- LPA | c.5092G>T p.G1698W | Missense Mutation (SNP) | VAF 20/598 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); called by muse, mutect2
- LRFN3 | c.80C>A p.P27Q | Missense Mutation (SNP) | VAF 15/366 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2
- LRRK2 | c.3778A>T p.I1260F | Missense Mutation (SNP) | VAF 50/404 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- MACC1 | c.56C>T p.S19F | Missense Mutation (SNP) | VAF 159/266 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); called by muse, mutect2, varscan2
- MAG | c.521G>T p.W174L | Missense Mutation (SNP) | VAF 24/568 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.167); called by muse, mutect2
- MAP1B | c.3104A>G p.E1035G | Missense Mutation (SNP) | VAF 16/359 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.476); called by muse, mutect2
- MATN2 | c.634C>A p.H212N | Missense Mutation (SNP) | VAF 15/346 reads (4%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.952); called by muse, mutect2
- MGAM | c.5358T>A p.N1786K | Missense Mutation (SNP) | VAF 9/161 reads (6%) | SIFT tolerated (0.42); PolyPhen benign (0.005); called by muse, mutect2
- MGAT5 | c.1462C>G p.P488A | Missense Mutation (SNP) | VAF 7/109 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- MLST8 | c.538C>T p.P180S | Missense Mutation (SNP) | VAF 66/187 reads (35%) | SIFT tolerated (0.64); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- MMP7 | c.179A>G p.K60R | Missense Mutation (SNP) | VAF 18/378 reads (5%) | SIFT tolerated (0.29); PolyPhen benign (0.013); called by muse, mutect2
- MRPL47 | c.37G>A p.V13I | Missense Mutation (SNP) | VAF 73/164 reads (45%) | SIFT tolerated (0.42); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- MSI2 | c.743C>A p.A248D | Missense Mutation (SNP) | VAF 14/316 reads (4%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.802); called by muse, mutect2
- MYLK | c.2843C>A p.P948H | Missense Mutation (SNP) | VAF 13/326 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- MYORG | c.1275G>T p.W425C | Missense Mutation (SNP) | VAF 20/378 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NACC2 | c.1433C>A p.P478H | Missense Mutation (SNP) | VAF 14/248 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2
- NCK2 | c.874C>T p.R292W | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NFATC4 | c.662C>G p.S221C | Missense Mutation (SNP) | VAF 13/317 reads (4%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); called by muse, mutect2
- NKX1-1 | c.310G>T p.G104C | Missense Mutation (SNP) | VAF 12/288 reads (4%) | SIFT deleterious, low confidence (0); called by muse, mutect2
- NOTCH3 | c.3222G>T p.E1074D | Missense Mutation (SNP) | VAF 22/668 reads (3%) | SIFT tolerated (0.37); PolyPhen benign (0.001); called by muse, mutect2
- OR11H7 | c.317C>A p.S106Y | Missense Mutation (SNP) | VAF 9/131 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2
- OR4X2 | c.263G>C p.G88A | Missense Mutation (SNP) | VAF 14/328 reads (4%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.798); called by muse, mutect2
- OSGEP | c.236-2A>T p.X79_splice | Splice Site (SNP) | VAF 7/139 reads (5%) | called by muse, mutect2
- PCDH12 | c.2714C>T p.A905V | Missense Mutation (SNP) | VAF 230/454 reads (51%) | SIFT tolerated (0.13); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- PCDHAC1 | c.2664C>A p.N888K | Missense Mutation (SNP) | VAF 16/426 reads (4%) | SIFT tolerated (0.26); PolyPhen benign (0.443); called by muse, mutect2
- PCDHB4 | c.1276G>A p.G426R | Missense Mutation (SNP) | VAF 26/640 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PCDHGA1 | c.227C>T p.A76V | Missense Mutation (SNP) | VAF 17/304 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.363); called by muse, mutect2
- PCDHGC3 | c.1694C>A p.P565H | Missense Mutation (SNP) | VAF 19/380 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- PCNX3 | c.5963C>G p.P1988R | Missense Mutation (SNP) | VAF 17/407 reads (4%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.987); called by muse, mutect2
- PDE6B | c.1700A>G p.Q567R | Missense Mutation (SNP) | VAF 36/722 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); called by muse, mutect2
- PHC3 | c.2140G>T p.G714* (on ENST00000494943 / NM_001308116.2; = p.G726* on NM_024947.4) | Nonsense Mutation (SNP) | VAF 16/310 reads (5%) | called by muse, mutect2
- PHLDA1 | c.137C>A p.A46D | Missense Mutation (SNP) | VAF 10/174 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.168); called by muse, mutect2
- PHLDB1 | c.1002C>G p.S334R | Missense Mutation (SNP) | VAF 17/388 reads (4%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.446); called by muse, mutect2
- PIGV | c.1445G>T p.G482V | Missense Mutation (SNP) | VAF 15/379 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PIK3R5 | c.761G>A p.R254K | Missense Mutation (SNP) | VAF 20/500 reads (4%) | SIFT tolerated (0.95); PolyPhen benign (0.001); called by muse, mutect2
- PIM2 | c.850C>T p.P284S | Missense Mutation (SNP) | VAF 16/248 reads (6%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.643); called by muse, mutect2
- PKP1 | c.390C>A p.Y130* | Nonsense Mutation (SNP) | VAF 39/719 reads (5%) | called by muse, mutect2
- PLCG1 | c.2305C>T p.P769S | Missense Mutation (SNP) | VAF 17/411 reads (4%) | SIFT tolerated (0.7); PolyPhen benign (0.003); called by muse, mutect2
- PODN | c.1493C>A p.P498H (on ENST00000395871; = p.P450H on NM_153703.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/342 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- POLR2A | c.3263G>C p.G1088A | Missense Mutation (SNP) | VAF 22/373 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- POM121C | c.80G>T p.G27V | Missense Mutation (SNP) | VAF 32/877 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.266); called by muse, mutect2
- PPOX | c.253C>A p.L85M | Missense Mutation (SNP) | VAF 28/862 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2
- PPP1R16A | c.613G>C p.A205P | Missense Mutation (SNP) | VAF 16/365 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); called by muse, mutect2
- PRAMEF18 | c.814C>A p.L272I | Missense Mutation (SNP) | VAF 142/699 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- PRDM15 | c.1105G>T p.D369Y | Missense Mutation (SNP) | VAF 17/444 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2
- PSD4 | c.1669G>C p.G557R | Missense Mutation (SNP) | VAF 24/491 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.006); called by muse, mutect2
- PSMD12 | c.865C>T p.R289* | Nonsense Mutation (SNP) | VAF 31/181 reads (17%) | called by muse, mutect2, varscan2
- PTAFR | c.959C>A p.A320D | Missense Mutation (SNP) | VAF 10/220 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0.039); called by muse, mutect2
- PTPN1 | c.625G>T p.G209W | Missense Mutation (SNP) | VAF 23/410 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PTPRS | c.4011C>A p.D1337E | Missense Mutation (SNP) | VAF 14/334 reads (4%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); called by muse, mutect2
- RALYL | c.845G>A p.G282E | Missense Mutation (SNP) | VAF 8/130 reads (6%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.522); called by muse, mutect2
- RASIP1 | c.784C>G p.R262G | Missense Mutation (SNP) | VAF 39/213 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- RELN | c.8287T>A p.C2763S | Missense Mutation (SNP) | VAF 22/712 reads (3%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.833); called by muse, mutect2
- RHOBTB3 | c.1148_1161+4del p.X383_splice | Splice Site (DEL) | VAF 28/77 reads (36%) | called by mutect2, pindel, varscan2
- RIPOR2 | c.798+1G>T p.X266_splice | Splice Site (SNP) | VAF 10/154 reads (6%) | called by muse, mutect2
- RND3 | c.484G>A p.G162R | Missense Mutation (SNP) | VAF 9/151 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RNF220 | c.758G>T p.S253I | Missense Mutation (SNP) | VAF 10/189 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.007); called by muse, mutect2
- RP1L1 | c.2518G>T p.G840* | Nonsense Mutation (SNP) | VAF 11/258 reads (4%) | called by muse, mutect2
- RPLP1 | c.146_147delinsGATGTTTGCAA p.X49_splice | Splice Site (INS) | VAF 40/168 reads (24%) | called by mutect2*, pindel, varscan2*
- SBSN | c.1547C>A p.A516D (on ENST00000452271 / NM_001166034.2; = p.A173D on NM_198538.4) | Missense Mutation (SNP) | VAF 21/556 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.461); called by muse, mutect2
- SCPEP1 | c.1171C>G p.L391V | Missense Mutation (SNP) | VAF 94/200 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.731); called by muse, mutect2, varscan2
- SCUBE2 | c.2264C>T p.T755I (on ENST00000649792 / NM_001367977.2; = p.T698I on NM_020974.3) | Missense Mutation (SNP) | VAF 28/277 reads (10%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); called by muse, mutect2
- SEMA4G | c.2242G>T p.G748C (on ENST00000370250; = p.G753C on NM_017893.3) | Missense Mutation (SNP) | VAF 14/188 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.219); called by muse, mutect2
- SERPINE3 | c.853T>G p.W285G | Missense Mutation (SNP) | VAF 20/286 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- SH2B3 | c.1095C>G p.F365L | Missense Mutation (SNP) | VAF 32/924 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SH3TC1 | c.1482G>T p.E494D | Missense Mutation (SNP) | VAF 10/156 reads (6%) | SIFT tolerated (0.62); PolyPhen benign (0.005); called by muse, mutect2
- SHKBP1 | c.580G>C p.G194R | Missense Mutation (SNP) | VAF 14/372 reads (4%) | SIFT tolerated (0.81); PolyPhen benign (0.185); called by muse, mutect2
- SHPRH | c.2578G>T p.G860W | Missense Mutation (SNP) | VAF 12/172 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SIRPA | c.1445C>A p.P482H | Missense Mutation (SNP) | VAF 28/355 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- SLC16A12 | c.1249C>T p.L417F | Missense Mutation (SNP) | VAF 23/462 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.559); called by muse, mutect2
- SLC25A1 | c.748G>T p.G250C | Missense Mutation (SNP) | VAF 16/508 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SLC34A2 | c.1270G>T p.A424S | Missense Mutation (SNP) | VAF 30/858 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.777); called by muse, mutect2
- SLC7A14 | c.2159G>C p.W720S | Missense Mutation (SNP) | VAF 21/420 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2
- SNX8 | c.461G>A p.R154H | Missense Mutation (SNP) | VAF 201/423 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- SOGA1 | c.3616G>T p.D1206Y | Missense Mutation (SNP) | VAF 28/591 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.104); called by muse, mutect2
- SOX14 | c.169T>A p.Y57N | Missense Mutation (SNP) | VAF 30/631 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2
- SOX9 | c.863_864insTC p.F289Pfs*95 | Frame Shift Ins (INS) | VAF 104/656 reads (16%) | called by mutect2, pindel, varscan2
- SPATA31E1 | c.2784G>T p.E928D | Missense Mutation (SNP) | VAF 12/324 reads (4%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.889); called by muse, mutect2
- SRRM5 | c.1718G>T p.R573I | Missense Mutation (SNP) | VAF 32/984 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.348); called by muse, mutect2
- SSC5D | c.610C>T p.P204S | Missense Mutation (SNP) | VAF 16/364 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.197); called by muse, mutect2
- STRIP2 | c.781G>T p.A261S | Missense Mutation (SNP) | VAF 40/335 reads (12%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.59); called by muse, mutect2, varscan2
- SYNE1 | c.9180T>A p.N3060K (on ENST00000367255 / NM_182961.4; = p.N3067K on NM_033071.3) | Missense Mutation (SNP) | VAF 117/233 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.367); called by muse, varscan2
- SYT6 | c.1423G>T p.G475C (on ENST00000610222 / NM_001366225.1; = p.G390C on NM_205848.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 165/342 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SYT8 | c.750C>A p.C250* | Nonsense Mutation (SNP) | VAF 79/442 reads (18%) | called by muse, mutect2, varscan2
- TAGAP | c.1697C>T p.A566V | Missense Mutation (SNP) | VAF 131/383 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- TAS1R3 | c.490C>A p.Q164K | Missense Mutation (SNP) | VAF 18/430 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2
- TBC1D10C | c.522G>C p.Q174H | Missense Mutation (SNP) | VAF 15/368 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by muse, mutect2
- TEDC2 | c.914T>C p.L305P | Missense Mutation (SNP) | VAF 14/277 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TEX13B | c.806C>A p.A269D | Missense Mutation (SNP) | VAF 32/750 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.866); called by muse, mutect2
- TF | c.1612G>T p.G538C | Missense Mutation (SNP) | VAF 107/283 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TFAP2B | c.1051C>T p.H351Y | Missense Mutation (SNP) | VAF 17/555 reads (3%) | SIFT tolerated (1); PolyPhen probably damaging (0.988); called by muse, mutect2
- TLR1 | c.1878A>G p.I626M | Missense Mutation (SNP) | VAF 208/453 reads (46%) | SIFT tolerated (0.15); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- TLX1 | c.707A>G p.K236R | Missense Mutation (SNP) | VAF 12/274 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.348); called by muse, mutect2
- TNF | c.379C>T p.P127S | Missense Mutation (SNP) | VAF 74/376 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TNFRSF25 | c.1171G>T p.G391* | Nonsense Mutation (SNP) | VAF 31/364 reads (9%) | called by muse, mutect2
- TRIP12 | c.5783-2A>G p.X1928_splice | Splice Site (SNP) | VAF 13/86 reads (15%) | called by muse, mutect2, varscan2
- TRIP6 | c.64G>A p.A22T | Missense Mutation (SNP) | VAF 14/324 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.015); called by muse, mutect2
- TRPV4 | c.1809C>A p.S603R | Missense Mutation (SNP) | VAF 148/940 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- UBASH3B | c.1027G>T p.G343W | Missense Mutation (SNP) | VAF 15/332 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.502); called by muse, mutect2
- UNC13C | c.5993A>G p.K1998R | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- VSTM1 | c.71-1G>C p.X24_splice | Splice Site (SNP) | VAF 42/218 reads (19%) | called by muse, mutect2, varscan2
- VSTM2B | c.497T>A p.I166N | Missense Mutation (SNP) | VAF 36/1093 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.011); called by muse, mutect2
- WDR97 | c.587G>A p.G196D | Missense Mutation (SNP) | VAF 30/692 reads (4%) | SIFT tolerated (0.48); PolyPhen benign (0.001); called by muse, mutect2
- XIRP2 | c.3112A>T p.S1038C (on ENST00000628543; = p.S1213C on NM_152381.6) | Missense Mutation (SNP) | VAF 7/146 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); called by muse, mutect2
- YAP1 | c.133C>A p.P45T | Missense Mutation (SNP) | VAF 36/522 reads (7%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); called by muse, mutect2
- ZBTB41 | c.2381A>C p.E794A | Missense Mutation (SNP) | VAF 81/530 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ZBTB46 | c.1528G>T p.A510S | Missense Mutation (SNP) | VAF 20/477 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.058); called by muse, mutect2
- ZFHX2 | c.6515C>T p.A2172V | Missense Mutation (SNP) | VAF 6/109 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.868); called by muse, mutect2
- ZHX1 | c.2272G>T p.G758W | Missense Mutation (SNP) | VAF 11/257 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ZNF148 | c.656A>G p.K219R | Missense Mutation (SNP) | VAF 22/164 reads (13%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ZNF268 | c.2005G>T p.G669* | Nonsense Mutation (SNP) | VAF 20/360 reads (6%) | called by muse, mutect2
- ZNF780B | c.83G>A p.R28K | Missense Mutation (SNP) | VAF 15/499 reads (3%) | SIFT tolerated (0.85); PolyPhen benign (0); called by muse, mutect2
- ZXDB | c.23C>T p.P8L | Missense Mutation (SNP) | VAF 92/220 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.11); called by muse, varscan2
- A1BG | c.717G>T p.V239= | Silent (SNP) | VAF 31/774 reads (4%) | catalogued as COSV54050821; called by muse, mutect2
- APOB | c.7527G>A p.K2509= | Silent (SNP) | VAF 14/282 reads (5%) | called by muse, mutect2
- ARID1A | c.2394C>T p.P798= | Silent (SNP) | VAF 8/189 reads (4%) | catalogued as COSV100254028; called by muse, mutect2
- AVPR1B | c.87G>T p.R29= | Silent (SNP) | VAF 17/264 reads (6%) | called by muse, mutect2
- BICRAL | c.2817G>T p.G939= | Silent (SNP) | VAF 22/406 reads (5%) | catalogued as COSV58407746; called by muse, mutect2
- C2CD5 | c.780C>T p.S260= | Silent (SNP) | VAF 47/279 reads (17%) | called by muse, mutect2, varscan2
- C4orf54 | c.2337C>T p.P779= | Silent (SNP) | VAF 111/218 reads (51%) | catalogued as rs1450567350; called by muse, mutect2, varscan2
- C8orf33 | c.171G>T p.A57= | Silent (SNP) | VAF 32/884 reads (4%) | called by muse, mutect2
- CAPN12 | c.555C>T p.Y185= | Silent (SNP) | VAF 62/265 reads (23%) | catalogued as rs751875254, COSV61018937; called by muse, mutect2, varscan2
- CD27 | c.162C>T p.D54= | Silent (SNP) | VAF 17/320 reads (5%) | called by muse, mutect2
- CDH22 | c.1242C>T p.G414= | Silent (SNP) | VAF 137/272 reads (50%) | catalogued as rs1420297759; called by muse, mutect2, varscan2
- CDH23 | c.4857C>T p.H1619= | Silent (SNP) | VAF 170/332 reads (51%) | catalogued as rs369817589; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- CFAP74 | c.3639G>A p.K1213= | Silent (SNP) | VAF 12/244 reads (5%) | called by muse, mutect2
- CLCA4 | c.63T>C p.T21= | Silent (SNP) | VAF 86/173 reads (50%) | catalogued as rs1006398304; called by muse, mutect2, varscan2
- CNBD2 | c.964C>T p.L322= | Silent (SNP) | VAF 23/269 reads (9%) | catalogued as COSV62587527, COSV62588248; called by muse, mutect2
- COL9A2 | c.828T>A p.A276= | Silent (SNP) | VAF 22/685 reads (3%) | called by muse, mutect2
- CSMD1 | c.8058G>A p.P2686= (on ENST00000520002; = p.P2685= on NM_033225.6) | Silent (SNP) | VAF 77/143 reads (54%) | catalogued as rs376009667; called by muse, mutect2, varscan2
- CTAG2 | c.471C>T p.S157= | Silent (SNP) | VAF 130/256 reads (51%) | catalogued as rs1557241414, COSV55996980; called by muse, varscan2
- CTU1 | c.369G>T p.G123= | Silent (SNP) | VAF 20/546 reads (4%) | called by muse, mutect2
- CUBN | c.3615G>T p.L1205= | Silent (SNP) | VAF 18/397 reads (5%) | called by muse, mutect2
- CYP27A1 | c.870C>T p.L290= | Silent (SNP) | VAF 176/399 reads (44%) | catalogued as rs202136743; called by muse, mutect2, varscan2
- EFCAB7 | c.1107T>A p.P369= | Silent (SNP) | VAF 11/134 reads (8%) | called by muse, mutect2
- ELOA2 | c.1245C>T p.N415= | Silent (SNP) | VAF 325/708 reads (46%) | catalogued as rs767658717; called by muse, mutect2, varscan2
- ERAS | c.531C>T p.F177= | Silent (SNP) | VAF 137/277 reads (49%) | catalogued as rs782348492, COSV54432734; called by muse, mutect2, varscan2
- ERC2 | c.1104G>A p.P368= | Silent (SNP) | VAF 149/318 reads (47%) | catalogued as rs559591672, COSV99883835; called by muse, mutect2, varscan2
- FAM47E-STBD1 | c.30G>T p.P10= | Silent (SNP) | VAF 10/244 reads (4%) | called by muse, mutect2
- FAT3 | c.5421G>T p.R1807= | Silent (SNP) | VAF 14/144 reads (10%) | called by muse, mutect2
- FEZF2 | c.765G>A p.E255= | Silent (SNP) | VAF 34/528 reads (6%) | catalogued as rs752923973; called by muse, mutect2
- FNDC1 | c.2070C>T p.G690= | Silent (SNP) | VAF 30/130 reads (23%) | catalogued as rs368786170; called by muse, mutect2, varscan2
- FOXF1 | c.180C>T p.A60= | Silent (SNP) | VAF 261/514 reads (51%) | catalogued as rs891128602; called by muse, mutect2, varscan2
- FURIN | c.2310G>A p.E770= | Silent (SNP) | VAF 28/360 reads (8%) | catalogued as rs892326275; called by muse, mutect2
- GASK1A | c.453G>T p.L151= | Silent (SNP) | VAF 11/245 reads (4%) | catalogued as rs1315454287; called by muse, mutect2
- GBP6 | c.30C>A p.P10= | Silent (SNP) | VAF 10/104 reads (10%) | called by muse, mutect2
- GPR45 | c.243C>T p.I81= | Silent (SNP) | VAF 62/410 reads (15%) | called by muse, mutect2, varscan2
- HAS1 | c.1242C>T p.F414= | Silent (SNP) | VAF 130/747 reads (17%) | catalogued as rs1385939899, COSV55788427; called by muse, mutect2, varscan2
- HCRTR1 | c.534C>A p.P178= | Silent (SNP) | VAF 27/568 reads (5%) | called by muse, mutect2
- KAT6A | c.1593C>T p.Y531= | Silent (SNP) | VAF 43/267 reads (16%) | catalogued as rs748947906; called by muse, mutect2, varscan2
- KBTBD8 | c.390C>T p.F130= | Silent (SNP) | VAF 13/195 reads (7%) | catalogued as rs1217410732; called by muse, mutect2
- KCNA1 | c.723C>T p.F241= | Silent (SNP) | VAF 549/721 reads (76%) | catalogued as rs147731985, COSV66836616; called by muse, mutect2, varscan2
- KCNK18 | c.117G>T p.V39= | Silent (SNP) | VAF 45/1035 reads (4%) | catalogued as COSV100572005; called by muse, mutect2
- KIAA2012 | c.423G>A p.E141= | Silent (SNP) | VAF 11/274 reads (4%) | called by muse, mutect2
- LPIN3 | c.2331G>T p.V777= | Silent (SNP) | VAF 21/410 reads (5%) | catalogued as COSV100182253; called by muse, mutect2
- LPL | c.132G>A p.R44= | Silent (SNP) | VAF 16/380 reads (4%) | catalogued as COSV100255816; called by muse, mutect2
- MAGI3 | c.3840A>G p.R1280= | Silent (SNP) | VAF 18/396 reads (5%) | called by muse, mutect2
- MAML3 | c.348G>C p.R116= | Silent (SNP) | VAF 35/765 reads (5%) | catalogued as COSV72209638; called by muse, mutect2
- MLNR | c.1176G>T p.G392= | Silent (SNP) | VAF 14/296 reads (5%) | called by muse, mutect2
- MPPED1 | c.303G>A p.R101= | Silent (SNP) | VAF 13/293 reads (4%) | called by muse, mutect2
- MROH1 | c.4338G>C p.G1446= | Silent (SNP) | VAF 36/916 reads (4%) | called by muse, mutect2
- MROH2A | c.2283C>A p.I761= | Silent (SNP) | VAF 15/320 reads (5%) | called by muse, mutect2
- OBSCN | c.7839G>A p.T2613= | Silent (SNP) | VAF 225/572 reads (39%) | catalogued as rs752520625; called by muse, mutect2, varscan2
- OCEL1 | c.186C>T p.P62= | Silent (SNP) | VAF 8/108 reads (7%) | called by muse, mutect2
- OPRL1 | c.165G>T p.V55= | Silent (SNP) | VAF 20/468 reads (4%) | catalogued as COSV100402021; called by muse, mutect2
- OSBPL7 | c.2133G>A p.R711= | Silent (SNP) | VAF 22/452 reads (5%) | catalogued as COSV99136858; called by muse, mutect2
- PCDH11X | c.3000C>A p.T1000= | Silent (SNP) | VAF 111/678 reads (16%) | catalogued as COSV53509930; called by muse, mutect2, varscan2
- PCDHA7 | c.1830G>A p.E610= | Silent (SNP) | VAF 37/770 reads (5%) | called by muse, mutect2
- PCDHB5 | c.714C>T p.N238= | Silent (SNP) | VAF 38/310 reads (12%) | catalogued as rs1320435155, COSV50647548; called by muse, mutect2, varscan2
- PDCD1 | c.747C>A p.A249= | Silent (SNP) | VAF 15/318 reads (5%) | called by muse, mutect2
- PEG10 | c.324C>A p.T108= (on ENST00000482108 / NM_001040152.2; = p.T142= on NM_015068.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 62/524 reads (12%) | called by muse, mutect2, varscan2
- PRAME | c.1149G>T p.L383= | Silent (SNP) | VAF 101/212 reads (48%) | called by muse, mutect2, varscan2
- PRKAB1 | c.609C>G p.P203= | Silent (SNP) | VAF 14/260 reads (5%) | called by muse, mutect2
- PRKAR1B | c.678C>T p.I226= | Silent (SNP) | VAF 18/322 reads (6%) | catalogued as rs1357406667; called by muse, mutect2
- PTGIR | c.459G>A p.L153= | Silent (SNP) | VAF 26/642 reads (4%) | called by muse, mutect2
- PVALB | c.285C>T p.D95= | Silent (SNP) | VAF 105/269 reads (39%) | catalogued as rs779969972, COSV53411865; called by muse, mutect2, varscan2
- RAB3IP | c.1167C>T p.C389= (on ENST00000550536 / NM_175623.4; = p.C373= on NM_022456.5) | Silent (SNP) | VAF 207/245 reads (84%) | catalogued as rs759943167, COSV56086458; called by muse, mutect2, varscan2
- RABGGTA | c.1497G>A p.E499= | Silent (SNP) | VAF 16/348 reads (5%) | called by muse, mutect2
- RAPSN | c.345C>T p.T115= | Silent (SNP) | VAF 32/603 reads (5%) | called by muse, mutect2
- RASGRF2 | c.2325G>A p.A775= | Silent (SNP) | VAF 167/391 reads (43%) | catalogued as rs1224821048, COSV54129465, COSV54129950; called by muse, mutect2, varscan2
- RPL3 | c.120G>T p.P40= | Silent (SNP) | VAF 26/558 reads (5%) | called by muse, mutect2
- RUSF1 | c.576C>A p.T192= | Silent (SNP) | VAF 39/252 reads (15%) | catalogued as COSV104401968; called by muse, mutect2, varscan2
- SEC14L5 | c.1548C>T p.S516= | Silent (SNP) | VAF 51/202 reads (25%) | catalogued as rs765045133, COSV52042344; called by muse, mutect2, varscan2
- SELPLG | c.129C>T p.A43= | Silent (SNP) | VAF 18/641 reads (3%) | catalogued as rs1431996943; called by muse, mutect2
- SHROOM4 | c.660C>T p.G220= | Silent (SNP) | VAF 20/527 reads (4%) | called by muse, mutect2
- SLC13A5 | c.663C>T p.T221= | Silent (SNP) | VAF 158/313 reads (50%) | catalogued as rs373831482; ClinVar: likely benign; called by muse, mutect2, varscan2
- SLC22A31 | c.906C>T p.A302= | Silent (SNP) | VAF 178/348 reads (51%) | catalogued as rs769295753; called by muse, mutect2, varscan2
- SLC35F3 | c.279G>A p.K93= (on ENST00000366617 / NM_001300845.1; = p.K162= on NM_173508.4) | Silent (SNP) | VAF 18/582 reads (3%) | called by muse, mutect2
- SPDYC | c.654C>A p.P218= | Silent (SNP) | VAF 16/232 reads (7%) | called by muse, mutect2
- SRGAP2C | c.618C>G p.S206= | Silent (SNP) | VAF 40/558 reads (7%) | called by muse, mutect2
- TNIK | c.3468A>G p.K1156= | Silent (SNP) | VAF 52/125 reads (42%) | catalogued as rs1388491392; called by muse, mutect2, varscan2
- TNN | c.2457G>A p.P819= | Silent (SNP) | VAF 173/424 reads (41%) | catalogued as rs370444325; called by muse, mutect2, varscan2
- TNXB | c.3687C>A p.T1229= (on ENST00000647633; = p.T982= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 20/486 reads (4%) | called by muse, mutect2
- TRMT44 | c.198G>A p.E66= | Silent (SNP) | VAF 79/194 reads (41%) | catalogued as rs1207453129; called by muse, mutect2, varscan2
- TSSK2 | c.657C>T p.S219= | Silent (SNP) | VAF 36/255 reads (14%) | catalogued as rs202209096; called by muse, mutect2, varscan2
- TTC28 | c.1287G>A p.E429= | Silent (SNP) | VAF 187/432 reads (43%) | called by muse, mutect2, varscan2
- UNC79 | c.1314C>T p.G438= (on ENST00000393151 / NM_001346218.2; = p.G261= on NM_020818.5) | Silent (SNP) | VAF 15/74 reads (20%) | catalogued as rs777242991, COSV99825428; called by muse, mutect2, varscan2
- USP6 | c.3375C>G p.P1125= | Silent (SNP) | VAF 15/320 reads (5%) | called by muse, mutect2
- WDR59 | c.1206C>T p.I402= | Silent (SNP) | VAF 17/253 reads (7%) | called by muse, mutect2
- WIZ | c.2661C>T p.T887= (on ENST00000673675 / NM_001371589.1; = p.T150= on NM_021241.3) | Silent (SNP) | VAF 15/391 reads (4%) | called by muse, mutect2
- XKR6 | c.465C>G p.R155= | Silent (SNP) | VAF 23/502 reads (5%) | called by muse, mutect2
- YPEL4 | c.6C>A p.P2= | Silent (SNP) | VAF 8/104 reads (8%) | called by muse, mutect2
- ZNF134 | c.936A>G p.G312= | Silent (SNP) | VAF 22/308 reads (7%) | called by muse, mutect2
- ZNF699 | c.615G>A p.V205= | Silent (SNP) | VAF 10/240 reads (4%) | catalogued as rs1252576041; called by muse, mutect2
- ABCG5 | c.-48G>T | 5'UTR (SNP) | VAF 16/332 reads (5%) | called by muse, mutect2
- AC024598.1 | c.1130-1482A>T | Intron (SNP) | VAF 12/214 reads (6%) | called by muse, mutect2
- AC091163.2 | n.600G>A | RNA (SNP) | VAF 8/162 reads (5%) | called by muse, mutect2
- ACE | c.*33C>T | 3'UTR (SNP) | VAF 18/393 reads (5%) | called by muse, mutect2
- AMFR | c.*412G>A | 3'UTR (SNP) | VAF 90/182 reads (49%) | catalogued as rs573375786; called by muse, mutect2, varscan2
- ARMCX4 | c.1039-4288G>T | Intron (SNP) | VAF 17/338 reads (5%) | catalogued as rs1556010582; called by muse, mutect2
- ATP6AP1L | n.1392C>T | RNA (SNP) | VAF 8/162 reads (5%) | called by muse, mutect2
- CACNB4 | c.1116+28_1116+30del | Intron (DEL) | VAF 42/92 reads (46%) | called by pindel, varscan2
- CAPS | chr19:5914206 C>A | 5'Flank (SNP) | VAF 26/540 reads (5%) | called by muse, mutect2
- CAPZB | c.3+1171G>A | Intron (SNP) | VAF 16/373 reads (4%) | called by muse, mutect2
- CCDC159 | c.22-530C>A | Intron (SNP) | VAF 20/488 reads (4%) | called by muse, mutect2
- COX14 | chr12:50123566 C>T | 3'Flank (SNP) | VAF 286/355 reads (81%) | catalogued as rs1378780531; called by muse, mutect2, varscan2
- DEFB119 | c.61+1245C>T | Intron (SNP) | VAF 18/442 reads (4%) | called by muse, mutect2
- DHRS11 | c.358-43T>C | Intron (SNP) | VAF 17/403 reads (4%) | catalogued as rs754398505; called by muse, mutect2
- DLG2 | c.205-65794G>A | Intron (SNP) | VAF 137/271 reads (51%) | catalogued as rs552998302, COSV54619672; called by muse, mutect2, varscan2
- EIF4H | c.469+949A>G | Intron (SNP) | VAF 20/198 reads (10%) | catalogued as COSV99733270; called by muse, mutect2, varscan2
- EML2 | c.1122+165A>G | Intron (SNP) | VAF 17/394 reads (4%) | called by muse, mutect2
- ENPP1 | c.556+46T>A | Intron (SNP) | VAF 88/503 reads (17%) | called by muse, mutect2, varscan2
- ETNPPL | c.1082+26T>C | Intron (SNP) | VAF 23/105 reads (22%) | called by muse, mutect2, varscan2
- EXT2 | c.*45G>T | 3'UTR (SNP) | VAF 10/244 reads (4%) | called by muse, mutect2
- FAM118A | c.-9-175G>A | Intron (SNP) | VAF 11/246 reads (4%) | called by muse, mutect2
- FBRSL1 | c.645+3436G>A | Intron (SNP) | VAF 22/578 reads (4%) | catalogued as rs939722101; called by muse, mutect2
- FES | c.214-33C>T | Intron (SNP) | VAF 12/215 reads (6%) | catalogued as rs1442018391; called by muse, mutect2
- FGFR1 | c.359-50A>T | Intron (SNP) | VAF 31/155 reads (20%) | called by muse, mutect2, varscan2
- FGFR3 | c.*867G>C | 3'UTR (SNP) | VAF 15/226 reads (7%) | called by muse, mutect2
- FLT4 | c.*8C>T | 3'UTR (SNP) | VAF 37/375 reads (10%) | catalogued as rs190791214, COSV99987271; called by muse, mutect2, varscan2
- GABRE | c.784+210G>T | Intron (SNP) | VAF 68/153 reads (44%) | called by muse, mutect2, varscan2
- GABRG2 | c.632-58C>T | Intron (SNP) | VAF 10/242 reads (4%) | called by muse, mutect2
- GLUD1 | c.1198-51G>T | Intron (SNP) | VAF 20/282 reads (7%) | called by muse, mutect2
- GSTO2 | c.468+6513A>G | Intron (SNP) | VAF 8/22 reads (36%) | called by muse, mutect2, varscan2
- HADH | c.133-4981G>A | Intron (SNP) | VAF 120/242 reads (50%) | catalogued as rs1329999456; called by muse, mutect2, varscan2
- HAPLN3 | c.493+826C>A | Intron (SNP) | VAF 35/183 reads (19%) | catalogued as rs775405803; called by muse, mutect2, varscan2
- INPPL1 | c.3686+39C>A | Intron (SNP) | VAF 8/158 reads (5%) | called by muse, mutect2
- MAD1L1 | c.1999-31294G>T | Intron (SNP) | VAF 28/732 reads (4%) | called by muse, mutect2
- MIR521-1 | n.56C>A | RNA (SNP) | VAF 79/233 reads (34%) | called by muse, mutect2, varscan2
- MMP17 | c.968+28C>T | Intron (SNP) | VAF 293/385 reads (76%) | catalogued as rs979007463, COSV62180959; called by muse, mutect2, varscan2
- MT1A | chr16:56636457 C>A | 5'Flank (SNP) | VAF 25/662 reads (4%) | called by muse, mutect2
- MYLK3 | c.2115-833G>A | Intron (SNP) | VAF 44/97 reads (45%) | catalogued as rs1377070022; called by muse, mutect2, varscan2
- OGT | c.532-93C>A | Intron (SNP) | VAF 9/37 reads (24%) | catalogued as rs759669893; called by muse, mutect2, varscan2
- POU3F2 | c.-3G>A | 5'UTR (SNP) | VAF 14/360 reads (4%) | catalogued as rs1462930095, COSV60409255; called by muse, mutect2
- PRDM16 | c.-48C>A | 5'UTR (SNP) | VAF 22/424 reads (5%) | called by muse, mutect2
- PRR3 | c.169+13G>A | Intron (SNP) | VAF 142/277 reads (51%) | called by muse, mutect2, varscan2
- PSIP1 | c.456+18C>T | Intron (SNP) | VAF 47/85 reads (55%) | called by muse, mutect2, varscan2
- QKI | c.1010-1237G>T | Intron (SNP) | VAF 7/120 reads (6%) | called by muse, mutect2
- RPS15 | chr19:1438392 G>T | 5'Flank (SNP) | VAF 23/702 reads (3%) | called by muse, mutect2
- SEC22A | c.-31A>G | 5'UTR (SNP) | VAF 34/154 reads (22%) | catalogued as rs1266496455; called by muse, mutect2, varscan2
- SLC16A2 | c.-131C>T | 5'UTR (SNP) | VAF 211/422 reads (50%) | called by muse, mutect2, varscan2
- SLC35A4 | c.*60C>T | 3'UTR (SNP) | VAF 10/222 reads (5%) | catalogued as COSV100021396; called by muse, mutect2
- SLC7A10 | c.1016+96G>C | Intron (SNP) | VAF 12/310 reads (4%) | called by muse, mutect2
- SSBP4 | c.1128+25C>A | Intron (SNP) | VAF 18/356 reads (5%) | catalogued as rs1401628248; called by muse, mutect2
- STK11IP | c.2869+64C>T | Intron (SNP) | VAF 23/662 reads (3%) | called by muse, mutect2
- SUV39H1 | c.*224C>A | 3'UTR (SNP) | VAF 8/86 reads (9%) | called by muse, mutect2
- TMEM204 | c.437-727G>A | Intron (SNP) | VAF 16/337 reads (5%) | catalogued as rs1349094760; called by muse, mutect2
- UQCR11 | c.-29G>A | 5'UTR (SNP) | VAF 18/590 reads (3%) | catalogued as rs1215671397; called by muse, mutect2
- ZNF384 | c.*120C>A | 3'UTR (SNP) | VAF 10/262 reads (4%) | catalogued as COSV100158786; called by muse, mutect2
- ZNF548 | c.16-2911G>T | Intron (SNP) | VAF 32/509 reads (6%) | called by muse, mutect2
